Gene-level copy-number profile of tumor specimen TCGA-B7-A5TI-01A from TCGA case TCGA-B7-A5TI, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.1 years (19,014 days).
Specimen TCGA-B7-A5TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.dd36995b-70b0-4db3-9991-33d2cb4e1ba4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B7-A5TI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7518aa38-3452-438e-9188-6c8cf417d52f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 12,525; copy number 2: 44,363; copy number 3: 2,906; copy number 4: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B7-A5TI-01A-11D-A31K-01): tumor purity 0.6, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:184,299,129–184,474,550, 5 genes (within-gene range 0–1): MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,282. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
